TCGA case TCGA-66-2794 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8d20352a-6180-40d0-adc0-c87fef854dfa

Demographics
Sex at birth: male; Country of residence at enrollment: Germany; Age at index: 64 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 64.9 years (23,710 days); Year of diagnosis: 2006; AJCC staging edition: 6th; AJCC pathologic T: T4; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,645 days (4.5 years).
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 606 days (1.7 years); Days to treatment end: 607 days (1.7 years); Treatment outcome: Complete Response; Treatment anatomic sites: Primary Tumor Field.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 1,645 days (4.5 years); Disease response: Tumor Free.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 100; Tobacco smoking onset year: 1957; Tobacco smoking quit year: 1993.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-66-2794-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.2; Intermediate dimension: 1; Shortest dimension: 0.3.
  Slide TCGA-66-2794-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 75; Percent normal cells: 5; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-66-2794-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 60; Percent normal cells: 15; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 30; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-66-2794-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-66-2794-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.5; Intermediate dimension: 1; Shortest dimension: 0.4.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tobacco smoking history indicator: 4; Anatomic organ subdivision: L-Upper.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,645 days; disease-specific survival: no event (censored), 1,645 days; disease-free interval: no event (censored), 1,645 days; progression-free interval: no event (censored), 1,645 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-66-2794-01A-01D-1195-01): tumor purity 0.64, ploidy 2.11, whole-genome doublings 0.
